Gene-level copy-number profile of tumor specimen TCGA-XU-AAXX-01A from TCGA case TCGA-XU-AAXX, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 44.5 years (16,265 days).
Specimen TCGA-XU-AAXX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.c120755e-d5b8-447e-a7fe-c03b37d88ad2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-AAXX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a139132c-02ef-441e-9a0f-5f8c30af4229

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 88; copy number 2: 59,702.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XU-AAXX-01A-11D-A427-01): tumor purity 0.27, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,335,514, 11 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 88. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
